Surgical pathology report (de-identified scan), TCGA case TCGA-58-8393, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-58-8393-01A (Primary Tumor).

TSS Name: [REDACTED]

TSS Identifier: [REDACTED]

TSS Unique Patient #: [REDACTED]

Pathology Report-Summary:

Material:

Lung, right, lower lobe: 20.0 x 14.0 x 7.5 cm

Tumor: 4.5 x 4.0 x 2.5 cm

Diagnosis:

Squamous Cell Carcinoma (NOS)

pT2a, pN0 (0/24), pMx, G2

Pathologist: [REDACTED]

Signature:

Date:

Source: NCI Genomic Data Commons file 6380a85c-a9f4-4b50-a9de-528d77a49b09 (TCGA-58-8393.BBC15D06-72EC-47E4-A65B-E3F7934AB41B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).